Gene-level copy-number profile of tumor specimen MP2PRT-PATVUA-TMP1-A from MP2PRT case MP2PRT-PATVUA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (956 days).
Specimen MP2PRT-PATVUA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e14fc18f-378d-4ed9-bb2a-cef8876d40ee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATVUA-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/ee4a12cd-6ea0-45bb-b8ee-4a254f8d9d50

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 127; copy number 2: 45,977; copy number 3: 9,206; copy number 4: 3,073.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
